Gene-level copy-number profile of tumor specimen TCGA-2G-AAGW-01A from TCGA case TCGA-2G-AAGW, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Yolk sac tumor; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IS; Age at diagnosis: 38.9 years (14,197 days).
Specimen TCGA-2G-AAGW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-TGCT.a1673bee-fab1-4f48-8526-c0736c75655a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-2G-AAGW-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/906c48b6-09dd-4912-86f9-56f3265cbb89

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 964; copy number 2: 29,834; copy number 3: 23,138; copy number 4: 2,715; copy number 5: 1,553; copy number 6: 714; copy number 9: 889.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-2G-AAGW-01A-11D-A42X-01): tumor purity 0.92, ploidy 2.83, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:15,314,920–15,324,472, 2 genes: RNU6-522P, RNU6-645P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,156 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:52,252,820–66,431,521, 184 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr6:34,889,255–45,377,953, 284 genes, copy number 5–6 (within-gene range 2–6) (broad region; genes not listed).
- chr6:53,561,289–58,438,364, 61 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr7:70,972–37,449,249, 658 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr7:71,685,452–72,836,701, 11 genes, copy number 5: RN7SKP75, CALN1, RNA5SP232, AC005011.1, ABCF2P2, TYW1B, MIR4650-2, AC211469.2, AC211469.1, RN7SL377P, SBDSP1.
- chr7:83,355,154–99,735,102, 244 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr7:106,624,072–108,884,587, 38 genes, copy number 5: AC005050.2, CCDC71L, LINC02577, RNA5SP236, PIK3CG, PRKAR2B, PRKAR2B-AS1, HBP1, AC004492.1, COG5, AC002381.1, GPR22, DUS4L, DUS4L-BCAP29, AC004839.2, BCAP29, AC004839.1, WBP1LP2, BANF1P5, SLC26A4-AS1, SLC26A4, AC002467.1, CBLL1, SLC26A3, PIGCP2, DLD, LAMB1, AC005046.1, U3, LAMB4, NRCAM, PNPLA8, RPL7P32, THAP5, DNAJB9, AC005487.1, AC002487.1, C7orf66.
- chr8:67,952,046–95,156,685, 417 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr8:95,206,876–95,216,525, 1 gene, copy number 5: LINC01298.
- chr8:99,796,615–113,950,998, 204 genes, copy number 5 (broad region; genes not listed).
- chr8:116,950,273–117,176,714, 1 gene, copy number 5 (within-gene range 4–5): SLC30A8.
- chr8:117,055,818–119,325,265, 20 genes, copy number 5: AC027419.1, AC027419.2, RN7SL826P, AC084114.1, AP002848.1, MED30, RPS10P16, EXT1, SAMD12, AC023590.1, SAMD12-AS1, RPS26P35, TNFRSF11B, RNU6-12P, AC107953.1, COLEC10, AC107953.2, MAL2, MAL2-AS1, MIR548AZ.
- chr12:66,767–40,570,832, 888 genes, copy number 9 (broad region; genes not listed).
- chr12:40,728,811–40,729,897, 1 gene, copy number 9: AC016144.1.
- chr17:19,112,000–21,594,180, 144 genes, copy number 5–6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 679. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
